Somatic mutation profile of tumor specimen 0DI1ZC from CCDI case PBBUDU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Mediastinum, NOS; Age at diagnosis: 14.0 years (5,111 days).
Specimen 0DI1ZC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b39e16e-a710-4ff3-834e-c66a33268a02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI1JN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ade8d66-2096-4559-963c-7574a50cfba1

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Splice Region 2, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C8orf82 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 105/259 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.11); catalogued as COSV52766833; called by muse, varscan2
- MYH6 | c.3382C>T p.R1128C | Missense Mutation (SNP) | VAF 72/416 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs727505211, COSV62451440; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NBEA | c.3221T>C p.M1074T | Missense Mutation (SNP) | VAF 443/973 reads (46%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs776620418; called by muse, mutect2, varscan2
- POMZP3 | c.65+3_65+6del | Splice Region (DEL) | VAF 176/454 reads (39%) | catalogued as rs774966717; called by mutect2, varscan2
- RAB11A | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 217/716 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.278); catalogued as COSV99976777; called by muse, mutect2, varscan2
- TMC4 | c.934C>T p.R312C (on ENST00000617472 / NM_001145303.3; = p.R306C on NM_144686.4) | Missense Mutation (SNP) | VAF 15/443 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as rs1384888041, COSV56599459; called by muse, mutect2
- ADAM8 | c.228G>A p.R76= | Splice Region (SNP) | VAF 87/194 reads (45%) | called by muse, mutect2, varscan2
- FGFR4 | c.1603A>G p.N535D | Missense Mutation (SNP) | VAF 145/346 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MGAT4B | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 110/253 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NUDT13 | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 84/372 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- STARD8 | c.2456A>G p.Y819C | Missense Mutation (SNP) | VAF 86/231 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CCDC185 | c.1473C>T p.R491= | Silent (SNP) | VAF 56/221 reads (25%) | catalogued as rs773606521, COSV64822154; called by muse, mutect2, varscan2
- UBA6 | c.2877C>T p.T959= | Silent (SNP) | VAF 213/871 reads (24%) | catalogued as rs761113535, COSV59174830; called by muse, mutect2, varscan2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 9/121 reads (7%) | called by muse, mutect2
- MED17 | c.1012+31C>T | Intron (SNP) | VAF 160/471 reads (34%) | catalogued as rs779400389; called by muse, mutect2, varscan2
- POU3F1 | c.*53del | 3'UTR (DEL) | VAF 7/56 reads (13%) | called by mutect2, varscan2
